Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAV2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAV2-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Copied To

Report Patient Name:
Demographics (for verification purposes) Date of Birth:
Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
Left liver at
Clinical Information
History of HCC and cirrhosis.
Infectious patient: Yes: Hep C +

ICD.O-3
Carcinoma, hepatocellular NOS S170/3
Site: Liver C22.0
Q4 5/20/14

Diagnosis

Left Liver, Resection:
- Hepatocellular carcinoma (please see synoptic)

Reported by:
Electronically signed by:
Verified:

Synoptic Report

Specimen:

Liver

PROCEDURE:

Partial hepatectomy

*Major hepatectomy (3 segments or more)

TUMOR SIZE:

Greatest dimension: 6.5 cm

TUMOR FOCALITY:

Solitary (specify location): Left Lobe

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GI: Well differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 15 mm

***VENOUS (LARGE VESSEL) INVASION (V):**

*Absent

***ADDITIONAL PATHOLOGIC FINDINGS:**

[page 2 of 2]
Cirrhosis/fibrosis*Gross Description**

Received is a single specimen container. The requisition and specimen container are labelled with the patient's name, The cassette and identifiers are labelled with the Surgical Number

Specimen is received fresh. The container is designated "A: Left liver". Specimen consists of a portion of liver weighing 295.7 g and measuring 17.5 x 9.5 x 5.5 cm. The liver capsule is grossly unremarkable. The resection margin is dyed black. Upon sectioning a well circumscribed, green mass is identified, measuring 6.5 x 6.0 x 5.0 cm. This mass grossly extends up to, but does not invade through the liver capsule and comes within 1.7 cm of the resection margin. Representative sections are submitted as follows:

- A1 to 3. sections of the mass in relation to the liver capsule
- A4. section of the mass in relation to the black painted resection margin
- A5. section of grossly unremarkable liver parenchyma

Microscopic Description

The well differentiated hepatocellular carcinomas shows areas of pseudoglandular growth.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 17e9a1bc-628b-414f-a981-835a8c505b26 (TCGA-G3-AAV2.A323CDD5-4022-486C-B77E-F0552FB9076B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).